Somatic mutation profile of tumor specimen MMRF_2055_1_BM_CD138pos (aliquot MMRF_2055_1_BM_CD138pos_T1_KHS5U_L08646) from MMRF case MMRF_2055, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 84.6 years (30,907 days).
Specimen MMRF_2055_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ec5de388-0ab8-406f-919a-cdd1487ca28d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2055_1_PB_Whole (Blood Derived Normal), aliquot MMRF_2055_1_PB_Whole_C2_KHS5U_L08647; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f8040d48-7f6f-4c07-ab95-a3f620a9afb7

The open-access MAF lists 196 somatic variants for this specimen: 79 protein-altering or splice-affecting, 25 silent, 92 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 69, 3'UTR 41, Silent 25, Intron 24, 5'UTR 12, RNA 6, 5'Flank 5, Nonsense Mutation 4, 3'Flank 4, Frame Shift Del 2, Splice Site 2, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1517G>A p.G506E (on ENST00000288602 / NM_001374244.1; = p.G466E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 64/196 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs121913351, CM115083, COSV56057462, COSV56059390, COSV56070593; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- NRAS | c.183A>C p.Q61H | Missense Mutation (SNP) | VAF 40/42 reads (95%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.316); catalogued as rs121913255, COSV54736320, COSV54736991, COSV54744813; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCB4 | c.2897G>C p.G966A | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.506); catalogued as COSV55934246; called by muse, mutect2, varscan2
- ANXA7 | c.1442T>G p.L481R (on ENST00000372919 / NM_001320880.2; = p.L459R on NM_001156.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 92/227 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs759709531; called by muse, mutect2, varscan2
- C9orf43 | c.31G>A p.E11K | Missense Mutation (SNP) | VAF 52/239 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1288623032; called by muse, mutect2, varscan2
- CPSF2 | c.2035A>G p.M679V | Missense Mutation (SNP) | VAF 76/162 reads (47%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs557180056; called by muse, mutect2, varscan2
- CUX2 | c.2044G>A p.G682S | Missense Mutation (SNP) | VAF 28/55 reads (51%) | SIFT tolerated (0.55); PolyPhen benign (0.05); catalogued as rs866576536; called by muse, mutect2, varscan2
- DHX37 | c.3125G>A p.R1042H | Missense Mutation (SNP) | VAF 29/73 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.902); catalogued as rs201416687; called by muse, mutect2, varscan2
- EVC | c.1690A>G p.N564D | Missense Mutation (SNP) | VAF 57/117 reads (49%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs946771615; called by muse, mutect2
- FAT3 | c.8425G>A p.D2809N | Missense Mutation (SNP) | VAF 66/167 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs867687680; called by muse, mutect2, varscan2
- FSCN1 | c.1202C>T p.T401M | Missense Mutation (SNP) | VAF 70/119 reads (59%) | SIFT deleterious (0.03); PolyPhen benign (0.075); catalogued as rs139232758; called by muse, mutect2, varscan2
- HPN | c.623G>A p.R208Q | Missense Mutation (SNP) | VAF 34/134 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.012); catalogued as rs761123733, COSV52882373; called by muse, mutect2, varscan2
- IGHD6-13 | c.5A>G p.Y2C | Missense Mutation (SNP) | VAF 61/64 reads (95%) | catalogued as rs782570981; called by muse, varscan2
- IGHJ3 | c.8T>C p.F3S | Missense Mutation (SNP) | VAF 37/37 reads (100%) | PolyPhen probably damaging (0.93); catalogued as rs372359611; called by muse, mutect2, varscan2
- IGHV2-70 | c.299T>C p.V100A | Missense Mutation (SNP) | VAF 41/86 reads (48%) | SIFT tolerated (0.48); PolyPhen benign (0.37); catalogued as rs192620545; called by muse, varscan2
- IGHV2-70D | c.235T>C p.F79L | Missense Mutation (SNP) | VAF 40/40 reads (100%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs1457244699; called by muse, varscan2
- IGLV2-23 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 17/50 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.916); catalogued as rs1208431435; called by muse, mutect2, varscan2
- KDM2A | c.2287C>G p.L763V | Missense Mutation (SNP) | VAF 47/110 reads (43%) | SIFT tolerated (0.21); PolyPhen benign (0.013); catalogued as COSV58190794; called by muse, mutect2, varscan2
- MFHAS1 | c.1529G>A p.R510H | Missense Mutation (SNP) | VAF 57/114 reads (50%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV52285445; called by muse, mutect2, varscan2
- NRXN2 | c.3664G>A p.D1222N | Missense Mutation (SNP) | VAF 43/77 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV55450970; called by muse, mutect2, varscan2
- ODF2 | c.2212C>T p.R738* (on ENST00000434106 / NM_153433.2; = p.R714* on NM_002540.5 and 4 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 70/243 reads (29%) | catalogued as rs779414875, COSV100654832; called by muse, mutect2, varscan2
- PPARGC1B | c.2537G>A p.R846Q | Missense Mutation (SNP) | VAF 30/103 reads (29%) | SIFT tolerated (0.38); PolyPhen benign (0.005); catalogued as rs780808898, COSV58529467; called by muse, varscan2
- PTK2B | c.2822G>A p.G941D | Missense Mutation (SNP) | VAF 23/52 reads (44%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV53559510; called by muse, mutect2, varscan2
- RBAK-RBAKDN | c.455C>T p.T152M | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.459); catalogued as rs777841791; called by muse, mutect2
- RIMS3 | c.777C>G p.I259M | Missense Mutation (SNP) | VAF 46/60 reads (77%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.881); catalogued as COSV101013580, COSV65504463; called by muse, mutect2, varscan2
- RIOK2 | c.1125A>C p.Q375H | Missense Mutation (SNP) | VAF 74/277 reads (27%) | SIFT tolerated (0.18); PolyPhen benign (0.011); catalogued as rs562480362; called by muse, mutect2, varscan2
- RNASEH2C | c.53C>G p.S18C | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.247); catalogued as COSV57729635; called by muse, mutect2, varscan2
- RNGTT | c.1520T>A p.L507Q | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV55651792; called by muse, mutect2, varscan2
- SATB2 | c.62C>A p.P21Q | Missense Mutation (SNP) | VAF 26/52 reads (50%) | SIFT tolerated (0.19); PolyPhen benign (0.215); catalogued as COSV53478323; called by muse, mutect2, varscan2
- SYT3 | c.18G>C p.E6D | Missense Mutation (SNP) | VAF 38/131 reads (29%) | SIFT tolerated (0.51); PolyPhen benign (0.001); catalogued as rs144585182; called by muse, mutect2, varscan2
- TBXAS1 | c.1112T>C p.V371A | Missense Mutation (SNP) | VAF 44/142 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.714); catalogued as rs748027473; called by muse, mutect2, varscan2
- TRBV19 | c.262G>A p.E88K | Missense Mutation (SNP) | VAF 45/164 reads (27%) | SIFT tolerated (0.81); PolyPhen benign (0.011); catalogued as rs1194888218; called by muse, mutect2, varscan2
- WDR72 | c.172C>G p.L58V | Missense Mutation (SNP) | VAF 32/185 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1197563611; called by muse, mutect2, varscan2
- WNT3 | c.778C>T p.R260W | Missense Mutation (SNP) | VAF 113/215 reads (53%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV56644345; called by muse, mutect2, varscan2
- ZFP62 | c.2349A>C p.K783N (on ENST00000502412 / NM_001377944.1; = p.K750N on NM_152283.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 63/111 reads (57%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV63091075; called by muse, mutect2, varscan2
- ZNF408 | c.1358G>A p.R453Q | Missense Mutation (SNP) | VAF 44/85 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.23); catalogued as rs369247386; called by muse, mutect2, varscan2
- ZNF528 | c.241G>A p.G81S | Missense Mutation (SNP) | VAF 12/333 reads (4%) | SIFT tolerated (0.22); PolyPhen benign (0.23); catalogued as rs1490054279, COSV100846605; called by muse, mutect2
- ANGPTL4 | c.784G>T p.V262L | Missense Mutation (SNP) | VAF 83/127 reads (65%) | SIFT deleterious (0.03); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- C4BPA | c.1562A>T p.Q521L | Missense Mutation (SNP) | VAF 24/86 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.333); called by muse, mutect2, varscan2
- CCL2 | c.77-1G>A p.X26_splice | Splice Site (SNP) | VAF 68/177 reads (38%) | called by muse, mutect2, varscan2
- CHL1 | c.1415A>C p.H472P (on ENST00000397491 / NM_001253387.1; = p.H488P on NM_006614.4) | Missense Mutation (SNP) | VAF 91/296 reads (31%) | SIFT tolerated (0.21); PolyPhen benign (0.377); called by muse, mutect2, varscan2
- CNOT2 | c.151C>T p.P51S | Missense Mutation (SNP) | VAF 13/118 reads (11%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.133); called by muse, mutect2, varscan2
- CNTNAP3B | c.880_882del p.H294del | In Frame Del (DEL) | VAF 52/316 reads (16%) | called by pindel, varscan2
- DMRTC2 | c.965C>T p.S322F | Missense Mutation (SNP) | VAF 57/203 reads (28%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- DNAH11 | c.3316G>C p.D1106H | Missense Mutation (SNP) | VAF 12/154 reads (8%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.622); called by muse, mutect2
- DNAH11 | c.3673A>G p.T1225A | Missense Mutation (SNP) | VAF 33/84 reads (39%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.874); called by muse, mutect2, varscan2
- DNAH11 | c.3773A>G p.Q1258R | Missense Mutation (SNP) | VAF 90/317 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DNAH2 | c.3335G>T p.S1112I | Missense Mutation (SNP) | VAF 48/102 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- DST | c.4978A>G p.K1660E | Missense Mutation (SNP) | VAF 103/230 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0.23); called by muse, mutect2, varscan2
- EGLN1 | c.384_394del p.A129Rfs*114 | Frame Shift Del (DEL) | VAF 31/53 reads (58%) | called by mutect2, pindel
- ESYT1 | c.122_134del p.Q41Lfs*11 | Frame Shift Del (DEL) | VAF 15/54 reads (28%) | called by mutect2, pindel, varscan2
- FER1L6 | c.107A>T p.E36V | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- FGD3 | c.1035+1G>A p.X345_splice | Splice Site (SNP) | VAF 43/110 reads (39%) | called by muse, mutect2, varscan2
- FMOD | c.398G>A p.W133* | Nonsense Mutation (SNP) | VAF 45/142 reads (32%) | called by muse, mutect2, varscan2
- GLB1L3 | c.242C>T p.T81I | Missense Mutation (SNP) | VAF 43/92 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.345); called by muse, mutect2, varscan2
- HGD | c.442T>G p.Y148D | Missense Mutation (SNP) | VAF 40/130 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.761); called by muse, mutect2, varscan2
- IGLC2 | c.238A>G p.K80E | Missense Mutation (SNP) | VAF 39/158 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- KMT2B | c.7852G>T p.E2618* | Nonsense Mutation (SNP) | VAF 51/259 reads (20%) | called by muse, mutect2, varscan2
- LAMB2 | c.4693A>G p.S1565G | Missense Mutation (SNP) | VAF 84/254 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- MAGI1 | c.1126T>G p.Y376D | Missense Mutation (SNP) | VAF 77/188 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- MELTF | c.1565A>G p.N522S | Missense Mutation (SNP) | VAF 34/115 reads (30%) | SIFT tolerated (0.6); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- MMP16 | c.1160G>T p.G387V | Missense Mutation (SNP) | VAF 87/192 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- MPDZ | c.477C>G p.N159K | Missense Mutation (SNP) | VAF 44/148 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.765); called by muse, mutect2, varscan2
- MPP4 | c.386T>A p.I129K | Missense Mutation (SNP) | VAF 42/78 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.464); called by muse, mutect2, varscan2
- MYH15 | c.2013G>A p.M671I | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.102); called by muse, mutect2, varscan2
- MYH8 | c.1322G>A p.W441* | Nonsense Mutation (SNP) | VAF 55/116 reads (47%) | called by muse, mutect2, varscan2
- NFE2L3 | c.1856C>T p.T619I | Missense Mutation (SNP) | VAF 97/181 reads (54%) | SIFT tolerated (0.21); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PCDH15 | c.3217T>G p.S1073A | Missense Mutation (SNP) | VAF 68/142 reads (48%) | SIFT tolerated (0.33); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- PHIP | c.4489A>C p.K1497Q | Missense Mutation (SNP) | VAF 6/190 reads (3%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.007); called by muse, mutect2
- POLR2A | c.2334G>T p.K778N | Missense Mutation (SNP) | VAF 43/103 reads (42%) | SIFT tolerated (0.58); PolyPhen benign (0.075); called by muse, mutect2, varscan2
- POLR2A | c.2335A>T p.I779F | Missense Mutation (SNP) | VAF 42/102 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PPP1R26 | c.3287G>C p.G1096A | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- RRAD | c.577A>G p.T193A | Missense Mutation (SNP) | VAF 38/74 reads (51%) | SIFT tolerated (1); PolyPhen benign (0.003); called by mutect2, varscan2
- SERPINB11 | c.802T>G p.F268V | Missense Mutation (SNP) | VAF 53/112 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.075); called by muse, mutect2, varscan2
- TEKT4 | c.1066C>A p.L356M | Missense Mutation (SNP) | VAF 42/81 reads (52%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TFAP2B | c.1330G>C p.G444R | Missense Mutation (SNP) | VAF 9/183 reads (5%) | SIFT tolerated (0.05); PolyPhen benign (0.255); called by muse, mutect2
- TGIF1 | c.185T>A p.V62D (on ENST00000330513 / NM_001374396.1; = p.V82D on NM_003244.4) | Missense Mutation (SNP) | VAF 51/118 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- TPT1 | c.365T>G p.I122S | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.878); called by muse, mutect2
- TTC9C | c.358C>T p.H120Y | Missense Mutation (SNP) | VAF 24/44 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.527); called by muse, mutect2, varscan2
- ANXA7 | c.1443T>A p.L481= (on ENST00000372919 / NM_001320880.2; = p.L459= on NM_001156.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 91/226 reads (40%) | catalogued as rs774472096; called by muse, mutect2, varscan2
- ARL10 | c.124C>A p.R42= | Silent (SNP) | VAF 55/145 reads (38%) | called by muse, mutect2, varscan2
- CDH24 | c.1191C>T p.S397= | Silent (SNP) | VAF 22/39 reads (56%) | catalogued as rs780138714; called by muse, mutect2, varscan2
- CRX | c.453C>T p.G151= | Silent (SNP) | VAF 110/328 reads (34%) | catalogued as rs1229731409; called by muse, mutect2, varscan2
- DCHS1 | c.4497C>T p.R1499= | Silent (SNP) | VAF 30/63 reads (48%) | called by muse, mutect2, varscan2
- DLGAP2 | c.504G>C p.S168= | Silent (SNP) | VAF 5/98 reads (5%) | catalogued as COSV70104925; called by muse, mutect2
- GLRB | c.1395T>G p.V465= | Silent (SNP) | VAF 299/632 reads (47%) | called by muse, mutect2, varscan2
- HPN | c.525G>A p.P175= | Silent (SNP) | VAF 70/208 reads (34%) | catalogued as rs35890010; called by muse, mutect2, varscan2
- IGFBP3 | c.456G>A p.P152= | Silent (SNP) | VAF 39/56 reads (70%) | called by muse, mutect2, varscan2
- IGHV2-70 | c.225T>C p.D75= | Silent (SNP) | VAF 52/110 reads (47%) | catalogued as rs373801344; called by muse, varscan2
- IGLV3-25 | c.261A>G p.T87= | Silent (SNP) | VAF 72/140 reads (51%) | called by muse, varscan2
- LCT | c.4623C>T p.V1541= | Silent (SNP) | VAF 23/55 reads (42%) | called by muse, mutect2, varscan2
- LONRF3 | c.648G>A p.G216= | Silent (SNP) | VAF 28/28 reads (100%) | called by muse, mutect2, varscan2
- LRP1B | c.3696G>A p.K1232= | Silent (SNP) | VAF 82/176 reads (47%) | catalogued as COSV67198814; called by muse, mutect2, varscan2
- MARS1 | c.1527T>A p.G509= | Silent (SNP) | VAF 40/89 reads (45%) | called by muse, mutect2, varscan2
- MED13L | c.3945C>T p.I1315= | Silent (SNP) | VAF 4/16 reads (25%) | called by mutect2, varscan2
- MUTYH | c.63C>T p.A21= | Silent (SNP) | VAF 97/107 reads (91%) | catalogued as rs201982344; ClinVar: likely benign; called by muse, varscan2
- NPAS4 | c.207C>T p.L69= | Silent (SNP) | VAF 27/64 reads (42%) | catalogued as COSV60651790; called by muse, mutect2, varscan2
- OR52N1 | c.510C>T p.Y170= | Silent (SNP) | VAF 48/123 reads (39%) | called by muse, mutect2, varscan2
- PRICKLE3 | c.1668A>T p.S556= | Silent (SNP) | VAF 58/69 reads (84%) | called by muse, mutect2, varscan2
- RASEF | c.135C>T p.A45= | Silent (SNP) | VAF 20/73 reads (27%) | catalogued as rs767112915; called by muse, mutect2, varscan2
- SHROOM3 | c.615T>C p.Y205= | Silent (SNP) | VAF 23/51 reads (45%) | called by muse, mutect2, varscan2
- TEKT4 | c.171C>T p.A57= | Silent (SNP) | VAF 6/44 reads (14%) | catalogued as rs371155806; called by muse, mutect2, varscan2
- UROS | c.45C>G p.G15= | Silent (SNP) | VAF 48/95 reads (51%) | called by muse, mutect2, varscan2
- USH2A | c.7311C>T p.G2437= | Silent (SNP) | VAF 14/41 reads (34%) | catalogued as rs552327619, COSV100242691, COSV56351446; called by muse, mutect2, varscan2
- AC011294.1 | n.212_214del | RNA (DEL) | VAF 71/135 reads (53%) | called by pindel, varscan2
- AC142086.6 | n.1643G>A | RNA (SNP) | VAF 8/20 reads (40%) | catalogued as rs1242308934; called by muse, mutect2, varscan2
- AKR1B1 | c.742-81A>C | Intron (SNP) | VAF 76/257 reads (30%) | called by muse, varscan2
- AL713998.1 | chr6:67889266 T>C | 5'Flank (SNP) | VAF 7/17 reads (41%) | called by muse, mutect2, varscan2
- AP5Z1 | c.1806-82_1806-61del | Intron (DEL) | VAF 38/194 reads (20%) | called by mutect2, pindel
- APOA5 | c.*396G>A | 3'UTR (SNP) | VAF 58/114 reads (51%) | catalogued as rs1400639640; called by muse, mutect2, varscan2
- ARFGEF1 | c.-419C>G | 5'UTR (SNP) | VAF 11/32 reads (34%) | called by muse, mutect2, varscan2
- ASH2L | c.188+221T>C | Intron (SNP) | VAF 30/48 reads (63%) | called by muse, mutect2, varscan2
- AZGP1 | c.614-139G>T | Intron (SNP) | VAF 24/334 reads (7%) | catalogued as rs1436707834; called by muse, mutect2
- BMP6 | c.*395G>A | 3'UTR (SNP) | VAF 50/129 reads (39%) | called by muse, mutect2, varscan2
- BRK1 | c.*673T>C | 3'UTR (SNP) | VAF 26/79 reads (33%) | called by muse, mutect2, varscan2
- C1orf229 | n.1675C>T | RNA (SNP) | VAF 68/171 reads (40%) | called by muse, mutect2, varscan2
- CAB39 | c.*778T>A | 3'UTR (SNP) | VAF 22/59 reads (37%) | called by muse, mutect2, varscan2
- CABIN1 | c.1262+24T>C | Intron (SNP) | VAF 44/92 reads (48%) | called by muse, mutect2, varscan2
- CCDC73 | c.429+3143G>A | Intron (SNP) | VAF 33/69 reads (48%) | catalogued as rs944405411; called by muse, mutect2, varscan2
- CCL14 | c.79+892A>G | Intron (SNP) | VAF 14/38 reads (37%) | called by muse, mutect2, varscan2
- CDH8 | c.*1006G>T | 3'UTR (SNP) | VAF 23/48 reads (48%) | called by muse, mutect2, varscan2
- CHRDL1 | c.*248A>G | 3'UTR (SNP) | VAF 20/22 reads (91%) | called by muse, mutect2, varscan2
- CNTN5 | c.1580+37A>G | Intron (SNP) | VAF 21/40 reads (53%) | catalogued as rs1248689740; called by muse, mutect2, varscan2
- CPNE5 | c.1432-79C>G | Intron (SNP) | VAF 13/33 reads (39%) | called by muse, mutect2, varscan2
- CYP19A1 | c.-38-95G>A | Intron (SNP) | VAF 28/209 reads (13%) | called by muse, mutect2, varscan2
- CYP4Z2P | n.63C>T | RNA (SNP) | VAF 12/94 reads (13%) | called by muse, mutect2, varscan2
- DCHS2 | n.2653-446G>C | Intron (SNP) | VAF 28/63 reads (44%) | catalogued as rs1321455792; called by muse, mutect2, varscan2
- DCP1B | chr12:2004528 G>A | 5'Flank (SNP) | VAF 100/200 reads (50%) | catalogued as rs1050367944; called by muse, mutect2, varscan2
- DDX6 | chr11:118752010 A>T | 3'Flank (SNP) | VAF 7/66 reads (11%) | called by muse, mutect2
- DENND10P1 | n.866G>A | RNA (SNP) | VAF 8/178 reads (4%) | called by muse, mutect2
- DLC1 | c.1348+28821G>C | Intron (SNP) | VAF 13/38 reads (34%) | called by muse, mutect2, varscan2
- DRD5 | c.-32G>A | 5'UTR (SNP) | VAF 27/53 reads (51%) | catalogued as COSV100431623; called by muse, mutect2, varscan2
- EIF2D | c.-48G>C | 5'UTR (SNP) | VAF 49/174 reads (28%) | catalogued as COSV99662843; called by muse, mutect2, varscan2
- ENGASE | c.1038+324G>A | Intron (SNP) | VAF 8/16 reads (50%) | catalogued as rs757344417; called by muse, mutect2, varscan2
- EPB41L2 | c.2608-98G>T | Intron (SNP) | VAF 10/21 reads (48%) | called by muse, varscan2
- EXD3 | c.55+3085G>A | Intron (SNP) | VAF 27/96 reads (28%) | catalogued as rs1023396328; called by muse, mutect2, varscan2
- EXOC5 | c.*569G>A | 3'UTR (SNP) | VAF 32/69 reads (46%) | called by muse, mutect2, varscan2
- FBXO21 | c.*7G>A | 3'UTR (SNP) | VAF 28/58 reads (48%) | catalogued as rs1483582918; called by muse, mutect2, varscan2
- FDFT1 | c.100-231C>T | Intron (SNP) | VAF 7/14 reads (50%) | called by muse, mutect2, varscan2
- FOSL2 | c.-744G>C | 5'UTR (SNP) | VAF 21/48 reads (44%) | called by muse, mutect2, varscan2
- GDF11 | c.*936_*947del | 3'UTR (DEL) | VAF 38/88 reads (43%) | called by mutect2, pindel, varscan2
- GMFB | c.*2845C>T | 3'UTR (SNP) | VAF 15/42 reads (36%) | catalogued as rs1009188377; called by muse, mutect2, varscan2
- GOLGA7B | c.*2042G>C | 3'UTR (SNP) | VAF 42/81 reads (52%) | called by muse, mutect2, varscan2
- HMCN1 | c.*891T>C | 3'UTR (SNP) | VAF 51/168 reads (30%) | called by muse, mutect2, varscan2
- HYDIN2 | n.2172C>A | RNA (SNP) | VAF 12/40 reads (30%) | called by mutect2, varscan2
- IGLV3-21 | c.-19C>T | 5'UTR (SNP) | VAF 67/70 reads (96%) | called by muse, mutect2, varscan2
- IL17A | c.*1159T>G | 3'UTR (SNP) | VAF 72/127 reads (57%) | called by muse, mutect2, varscan2
- KCNA4 | c.-380A>G | 5'UTR (SNP) | VAF 18/41 reads (44%) | called by muse, mutect2, varscan2
- KCTD12 | c.*3172G>A | 3'UTR (SNP) | VAF 26/29 reads (90%) | called by muse, mutect2, varscan2
- LARP4B | c.*336T>G | 3'UTR (SNP) | VAF 16/47 reads (34%) | called by muse, mutect2, varscan2
- LHCGR | c.536+2327T>A | Intron (SNP) | VAF 27/66 reads (41%) | called by muse, mutect2, varscan2
- LIN28B | c.*4020A>T | 3'UTR (SNP) | VAF 85/227 reads (37%) | called by muse, mutect2, varscan2
- LRATD1 | c.*197C>T | 3'UTR (SNP) | VAF 46/98 reads (47%) | called by muse, mutect2, varscan2
- MBP | c.*1312C>T | 3'UTR (SNP) | VAF 38/83 reads (46%) | called by muse, mutect2, varscan2
- ME2 | c.*436A>C | 3'UTR (SNP) | VAF 20/48 reads (42%) | called by muse, mutect2, varscan2
- NDUFC2 | c.-85A>G | 5'UTR (SNP) | VAF 80/203 reads (39%) | called by muse, mutect2
- NDUFS7 | c.228+142A>G | Intron (SNP) | VAF 50/158 reads (32%) | catalogued as rs1237785022; called by muse, mutect2
- NUP210L | chr1:154155788 G>A | 5'Flank (SNP) | VAF 14/86 reads (16%) | called by muse, mutect2, varscan2
- OSBPL10 | c.*308C>T | 3'UTR (SNP) | VAF 24/76 reads (32%) | called by muse, mutect2, varscan2
- PDXK | c.*5537C>T | 3'UTR (SNP) | VAF 62/118 reads (53%) | called by muse, mutect2, varscan2
- POU2AF1 | c.*169C>A | 3'UTR (SNP) | VAF 31/48 reads (65%) | called by muse, mutect2, varscan2
- PROKR2 | chr20:5316538 C>T | 5'Flank (SNP) | VAF 22/55 reads (40%) | called by muse, mutect2
- PRPS1 | c.-45A>G | 5'UTR (SNP) | VAF 42/46 reads (91%) | called by muse, varscan2
- PTGES3 | c.-79A>G | 5'UTR (SNP) | VAF 3/21 reads (14%) | called by muse, mutect2
- PTPN2 | c.1143-98A>T | Intron (SNP) | VAF 40/113 reads (35%) | called by muse, mutect2
- RAN | c.-276G>A | 5'UTR (SNP) | VAF 59/126 reads (47%) | called by muse, mutect2, varscan2
- RNF157 | c.*2249A>C | 3'UTR (SNP) | VAF 53/125 reads (42%) | called by muse, mutect2, varscan2
- RPL10 | c.*237T>C | 3'UTR (SNP) | VAF 41/46 reads (89%) | called by muse, mutect2, varscan2
- RWDD1 | c.*264G>A | 3'UTR (SNP) | VAF 27/89 reads (30%) | catalogued as rs1419970180; called by muse, mutect2, varscan2
- S1PR3 | c.*613A>T | 3'UTR (SNP) | VAF 53/130 reads (41%) | called by muse, mutect2, varscan2
- SHROOM3 | c.*2703G>A | 3'UTR (SNP) | VAF 44/82 reads (54%) | catalogued as rs960873959; called by muse, mutect2, varscan2
- SLC17A6 | c.*405A>C | 3'UTR (SNP) | VAF 41/110 reads (37%) | called by muse, mutect2, varscan2
- SNORD114-23 | chr14:100987000 A>G | 3'Flank (SNP) | VAF 13/65 reads (20%) | catalogued as rs780469331; called by muse, mutect2, varscan2
- SOX11 | c.*3995A>T | 3'UTR (SNP) | VAF 5/59 reads (8%) | catalogued as COSV58983565; called by muse, mutect2
- SPG7 | c.1429-58C>T | Intron (SNP) | VAF 29/83 reads (35%) | called by muse, mutect2, varscan2
- STXBP5 | chr6:147385051 A>G | 3'Flank (SNP) | VAF 13/28 reads (46%) | called by muse, mutect2, varscan2
- SYNCRIP | chr6:85611611 A>T | 3'Flank (SNP) | VAF 28/61 reads (46%) | called by muse, mutect2, varscan2
- TJP1 | c.*1652_*1653insGT | 3'UTR (INS) | VAF 76/222 reads (34%) | called by mutect2, pindel, varscan2
- TJP1 | c.1010+1008C>T | Intron (SNP) | VAF 88/279 reads (32%) | called by muse, mutect2, varscan2
- TLNRD1 | c.-1000_-993del | 5'UTR (DEL) | VAF 23/92 reads (25%) | called by mutect2, varscan2
- TNNI3 | c.24+11C>T | Intron (SNP) | VAF 4/39 reads (10%) | called by muse, mutect2, varscan2
- TTC6 | chr14:37792276 G>A | 5'Flank (SNP) | VAF 50/91 reads (55%) | called by muse, mutect2, varscan2
- TYRP1 | c.*415C>T | 3'UTR (SNP) | VAF 8/47 reads (17%) | called by muse, mutect2, varscan2
- VEPH1 | c.*987A>C | 3'UTR (SNP) | VAF 36/89 reads (40%) | called by muse, mutect2, varscan2
- VPS35L | c.725-56T>G | Intron (SNP) | VAF 9/20 reads (45%) | called by muse, mutect2, varscan2
- VXN | c.*2181T>G | 3'UTR (SNP) | VAF 5/10 reads (50%) | called by muse, mutect2, varscan2
- WASL | c.*1147del | 3'UTR (DEL) | VAF 12/119 reads (10%) | catalogued as rs201393261; called by pindel, varscan2
- WDR33 | c.*4009G>A | 3'UTR (SNP) | VAF 24/52 reads (46%) | catalogued as rs1423503301; called by muse, mutect2, varscan2
- YWHAZ | c.*1193del | 3'UTR (DEL) | VAF 100/263 reads (38%) | called by mutect2, pindel, varscan2
- ZFHX3 | c.*3021A>T | 3'UTR (SNP) | VAF 55/121 reads (45%) | called by muse, mutect2, varscan2
- ZMIZ1 | c.*3150G>C | 3'UTR (SNP) | VAF 37/87 reads (43%) | called by muse, mutect2, varscan2
- ZNF106 | c.-12G>A | 5'UTR (SNP) | VAF 35/135 reads (26%) | called by muse, mutect2, varscan2
- ZNF385D | c.*425del | 3'UTR (DEL) | VAF 18/80 reads (23%) | catalogued as rs113101913, COSV99872942; called by mutect2, varscan2
- ZNF561 | c.*141T>C | 3'UTR (SNP) | VAF 45/196 reads (23%) | called by muse, mutect2, varscan2
- ZNF561 | c.25+141T>G | Intron (SNP) | VAF 16/44 reads (36%) | called by muse, varscan2
- ZNF703 | c.*820G>A | 3'UTR (SNP) | VAF 118/264 reads (45%) | catalogued as rs367856231; called by muse, mutect2
